Somatic mutation profile of tumor specimen 0DFHF8 from CCDI case PBBSEP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,580 days).
Specimen 0DFHF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d603c098-e61f-4165-8aba-0d7ef7c0c023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFHF9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e393928-6b29-4c37-9462-686b85411205

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGIF2LX | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 157/492 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as rs756446097, COSV52213962; called by muse, mutect2
- PCDHB2 | c.1971C>T p.T657= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as COSV99165485; called by muse, mutect2, varscan2
- OXA1L | c.405+15G>A | Intron (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
